Somatic mutation profile of tumor specimen 0DPSNL from CCDI case PBCDYN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,030 days).
Specimen 0DPSNL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed1a4166-30df-475e-b236-bee1975ed60a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPSN3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a24cdba-69a1-4538-8205-6309a079b5ca

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSPRY | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 80/500 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as rs377189582; called by muse, mutect2, varscan2
- OR6Q1 | c.257del p.G86Vfs*70 | Frame Shift Del (DEL) | VAF 29/288 reads (10%) | catalogued as COSV100110438; called by mutect2, varscan2
- ASB5 | c.-18G>A | 5'UTR (SNP) | VAF 10/174 reads (6%) | catalogued as rs1469861910, COSV56671028; called by muse, mutect2
